Somatic mutation profile of tumor specimen TCGA-UB-A7MF-01A (aliquot TCGA-UB-A7MF-01A-11D-A33K-10) from TCGA case TCGA-UB-A7MF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 57.0 years (20,815 days).
Specimen TCGA-UB-A7MF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa103367-ecc6-4012-b39a-9d557c13aef7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UB-A7MF-10A (Blood Derived Normal), aliquot TCGA-UB-A7MF-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d5b9357-579f-45ed-86c9-4f7ad35d344e

The open-access MAF lists 113 somatic variants for this specimen: 90 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 21, Frame Shift Del 6, Splice Site 4, Nonsense Mutation 4, Frame Shift Ins 1, 5'UTR 1, Translation Start Site 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.644G>T p.S215I | Missense Mutation (SNP) | VAF 53/113 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782177, COSV52679681, COSV52686793, COSV52700292, COSV52891297; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.7619C>T p.T2540I | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV55045953; called by muse, mutect2, varscan2
- ANXA9 | c.852+1G>A p.X284_splice | Splice Site (SNP) | VAF 41/112 reads (37%) | catalogued as rs775300431, COSV64484219; called by muse, mutect2, varscan2
- ARID1B | c.4604A>G p.N1535S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51650191; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2377C>G p.L793V | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59472897; called by muse, mutect2, varscan2
- BPIFB4 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64950766; called by muse, mutect2, varscan2
- BRINP2 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 76/269 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV64175671; called by muse, mutect2, varscan2
- C11orf49 | c.821+2dup p.X274_splice | Splice Site (INS) | VAF 16/80 reads (20%) | catalogued as rs34737621; called by mutect2, pindel, varscan2
- CACNA1H | c.3893A>G p.H1298R | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV61984756; called by muse, mutect2, varscan2
- CES3 | c.1592C>A p.P531Q | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs746873961, COSV57592762; called by muse, mutect2, varscan2
- CLEC4D | c.459G>T p.Q153H | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV55228189; called by muse, mutect2, varscan2
- COL6A2 | c.1574G>A p.G525E | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs954710683, COSV55999976; called by muse, mutect2, varscan2
- COLGALT1 | c.1730G>A p.W577* | Nonsense Mutation (SNP) | VAF 25/146 reads (17%) | catalogued as rs1179950598, COSV53107611; called by muse, mutect2, varscan2
- CRISPLD1 | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51544713, COSV51546099; called by muse, mutect2, varscan2
- CYTH1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63118652; called by muse, mutect2
- DBP | c.755A>G p.E252G | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV50032762, COSV50033018; called by muse, mutect2, varscan2
- DIPK1B | c.929A>G p.D310G | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63037727; called by muse, mutect2, varscan2
- DISC1 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 5/84 reads (6%) | catalogued as COSV54401293; called by muse, mutect2
- DNAH5 | c.8480A>G p.K2827R | Missense Mutation (SNP) | VAF 111/178 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV54206537; called by muse, mutect2, varscan2
- DNAJB13 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.964); catalogued as COSV60104339; called by muse, mutect2
- DNAJB7 | c.882A>C p.K294N | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53420952; called by muse, mutect2, varscan2
- DPEP2 | c.137T>A p.L46Q | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.571); catalogued as COSV52053916; called by muse, mutect2, varscan2
- DPH6 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 19/481 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV56613215, COSV99853940; called by muse, mutect2
- EFCAB3 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs768995121, COSV59500033; called by muse, mutect2, varscan2
- EIF2AK1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99552314; called by muse, mutect2
- EIF5A | c.44C>G p.S15* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV59747333; called by muse, mutect2, varscan2
- FIG4 | c.1955G>C p.C652S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57785293; called by muse, mutect2
- GNAL | c.377A>G p.D126G (on ENST00000269162 / NM_001142339.3; = p.D203G on NM_182978.4) | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV52323736; called by muse, mutect2, varscan2
- GPC2 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV52783987; called by muse, mutect2, varscan2
- GPR63 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs762800138, COSV57739767; called by muse, mutect2, varscan2
- GRIK2 | c.934C>A p.L312M | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV59714545; called by muse, mutect2, varscan2
- HOXC11 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV54532335; called by muse, mutect2, varscan2
- INTS7 | c.413A>G p.N138S | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as COSV65343741; called by muse, mutect2, varscan2
- KCNU1 | c.1084A>G p.T362A | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV67753456; called by muse, mutect2, varscan2
- LGSN | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.978); catalogued as COSV101040752, COSV65726327; called by muse, mutect2, varscan2
- MCF2L | c.3166G>A p.V1056I (on ENST00000375608; = p.V1024I on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV56175953; called by muse, mutect2
- MICU2 | c.893T>C p.I298T | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as rs762263379, COSV66673302; called by muse, mutect2, varscan2
- MLST8 | c.345-1G>C p.X115_splice | Splice Site (SNP) | VAF 33/141 reads (23%) | catalogued as rs1465181274, COSV57026723; called by muse, mutect2, varscan2
- MOSPD2 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 80/90 reads (89%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV66859675; called by muse, mutect2, varscan2
- MYH7 | c.2628G>C p.K876N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62516642; called by muse, mutect2, varscan2
- MYO6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV64117665; called by muse, mutect2, varscan2
- MYT1L | c.1469C>A p.P490Q | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.358); catalogued as COSV67710116; called by muse, mutect2, varscan2
- NDUFA10 | c.788C>A p.A263D | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV53152850; called by muse, mutect2, varscan2
- NFAT5 | c.2378del p.G793Efs*10 | Frame Shift Del (DEL) | VAF 15/72 reads (21%) | catalogued as COSV63032522; called by mutect2, pindel, varscan2
- NKTR | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51769601; called by muse, mutect2, varscan2
- NOVA2 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54356108; called by muse, mutect2, varscan2
- NR4A2 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV59892721; called by muse, mutect2, varscan2
- OR2L3 | c.18A>T p.Q6H | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV63454540, COSV63456333; called by muse, mutect2, varscan2
- OR9A2 | c.256T>C p.F86L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV63306329; called by muse, mutect2, varscan2
- P2RY1 | c.852G>C p.L284F | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV59308929; called by muse, mutect2, varscan2
- PAK5 | c.2128G>T p.V710F | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV62022013, COSV62029290; called by muse, mutect2, varscan2
- PCSK7 | c.824A>G p.N275S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.822); catalogued as COSV58005999; called by muse, mutect2, varscan2
- PIK3C2A | c.2231T>C p.L744P | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV56400663; called by muse, mutect2, varscan2
- PIWIL4 | c.2454T>G p.S818R | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54407888; called by muse, mutect2, varscan2
- PLCB1 | c.3572G>T p.G1191V | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV62039916; called by muse, mutect2, varscan2
- PLCG1 | c.3382A>G p.T1128A | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54815652; called by muse, mutect2
- PLCG2 | c.829A>T p.M277L | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV63867675; called by muse, mutect2, varscan2
- POTEH | c.427T>A p.F143I | Missense Mutation (SNP) | VAF 99/538 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); catalogued as COSV58880442; called by muse, mutect2, varscan2
- PTGDR | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV60093180; called by muse, mutect2
- RASSF4 | c.279T>A p.P93= | Splice Region (SNP) | VAF 28/72 reads (39%) | catalogued as COSV53573436; called by muse, mutect2, varscan2
- RIPK1 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 103/239 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as COSV52528076; called by muse, mutect2, varscan2
- SCARA5 | c.1027T>A p.L343M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV57275772; called by muse, mutect2, varscan2
- SDK1 | c.5180C>T p.P1727L | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs548946940, COSV67358000; called by muse, mutect2, varscan2
- SELP | c.1823T>G p.L608R | Missense Mutation (SNP) | VAF 10/287 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV55251301, COSV99741116; called by muse, mutect2
- SF3A1 | c.2084A>T p.E695V | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as COSV53167417; called by muse, mutect2, varscan2
- SH3GL3 | c.352G>C p.G118R | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61053710; called by muse, mutect2, varscan2
- SIGLEC12 | c.1255A>G p.T419A (on ENST00000291707 / NM_053003.4; = p.T301A on NM_033329.2) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.241); catalogued as COSV52459648; called by muse, mutect2, varscan2
- SLC6A15 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.491); catalogued as COSV57020459; called by muse, mutect2, varscan2
- SSX5 | c.105A>T p.K35N (on ENST00000347757 / NM_175723.1; = p.K76N on NM_021015.4) | Missense Mutation (SNP) | VAF 99/135 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV61254628; called by muse, mutect2, varscan2
- STAT1 | c.1957G>C p.V653L | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as COSV63115132; called by muse, mutect2, varscan2
- SYNPO2 | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 88/118 reads (75%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as COSV61107240; called by muse, mutect2, varscan2
- TBX3 | c.1897A>T p.T633S (on ENST00000257566 / NM_016569.4; = p.T613S on NM_005996.4) | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57469488; called by muse, mutect2, varscan2
- TET1 | c.5560A>G p.T1854A | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV65382395; called by muse, mutect2, varscan2
- TMEM200C | c.1669C>G p.Q557E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV67309184; called by muse, mutect2, varscan2
- TMOD3 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV100419146, COSV57942177, COSV57946323; called by muse, mutect2, varscan2
- TNR | c.2156C>G p.T719S | Missense Mutation (SNP) | VAF 86/162 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.309); catalogued as COSV54872640; called by muse, mutect2, varscan2
- TPP2 | c.3563A>T p.H1188L | Missense Mutation (SNP) | VAF 434/643 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65751171; called by muse, mutect2, varscan2
- TSLP | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 41/232 reads (18%) | catalogued as COSV61291298; called by muse, mutect2, varscan2
- UCP1 | c.127-1G>A p.X43_splice | Splice Site (SNP) | VAF 30/40 reads (75%) | catalogued as COSV53767374; called by muse, mutect2, varscan2
- VAC14 | c.105G>T p.K35N | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV55751287; called by muse, mutect2, varscan2
- VENTX | c.685C>G p.P229A | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as COSV58084103; called by muse, mutect2, varscan2
- ZNF175 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51794192; called by muse, mutect2
- ZNF385D | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs780010347, COSV55747228; called by muse, mutect2, varscan2
- B3GNTL1 | c.922del p.D308Tfs*26 | Frame Shift Del (DEL) | VAF 24/119 reads (20%) | called by mutect2, pindel, varscan2
- CWC22 | c.67_71del p.Y23Efs*10 | Frame Shift Del (DEL) | VAF 14/164 reads (9%) | called by mutect2, pindel
- FAM72A | c.303_304dup p.W102Sfs*15 | Frame Shift Ins (INS) | VAF 79/526 reads (15%) | called by mutect2, pindel, varscan2
- KANSL1 | c.2754_2758del p.L919Cfs*4 (on ENST00000574590 / NM_001193465.2; = p.L920Cfs*4 on NM_015443.4) | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | called by mutect2, pindel
- KIAA1217 | c.3983_3989del p.S1328Cfs*21 | Frame Shift Del (DEL) | VAF 39/118 reads (33%) | called by mutect2, pindel, varscan2
- OR8G2P | c.127T>G p.L43V | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF488 | c.1021_1022del p.*341Afs*59 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.2019T>A p.V673= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV67127240; called by muse, mutect2, varscan2
- ADRA2C | c.600G>A p.P200= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs762543294, COSV57466801; called by muse, mutect2, varscan2
- AFDN | c.5178C>T p.F1726= (on ENST00000447894 / NM_001366320.1; = p.F1683= on NM_001291964.1) | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV100653532; called by muse, mutect2, varscan2
- APEH | c.1999C>T p.L667= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV56532302; called by muse, mutect2, varscan2
- APOBEC3D | c.570T>C p.Y190= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as COSV53325745; called by muse, mutect2, varscan2
- ATP6V0D1 | c.1047T>A p.P349= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV52096894; called by muse, mutect2, varscan2
- CATIP | c.387C>T p.L129= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV56822177; called by muse, mutect2, varscan2
- ELANE | c.441C>T p.N147= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs146878885; called by muse, mutect2, varscan2
- FBN2 | c.3279C>A p.I1093= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV52495228, COSV52504788; called by muse, mutect2, varscan2
- GRIA4 | c.1542T>A p.S514= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV56883849; called by muse, mutect2, varscan2
- MYH8 | c.2649C>A p.L883= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV67960476; called by muse, mutect2, varscan2
- NAV2 | c.2856C>A p.S952= (on ENST00000396087 / NM_001244963.2; = p.S929= on NM_145117.5) | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as COSV100216283, COSV60656854; called by muse, mutect2, varscan2
- NEDD4L | c.1902A>G p.R634= (on ENST00000400345 / NM_001144967.3; = p.R614= on NM_015277.6) | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV56841000; called by muse, mutect2, varscan2
- NPR1 | c.1065C>T p.D355= | Silent (SNP) | VAF 85/204 reads (42%) | catalogued as rs200678502, COSV64140346; called by muse, mutect2, varscan2
- PC | c.264C>T p.R88= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs757830976, COSV63079196; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAI1 | c.510C>T p.S170= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV55389722; called by muse, mutect2, varscan2
- RUNX1T1 | c.546C>A p.I182= (on ENST00000265814 / NM_001198628.1; = p.I155= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV56138862; called by muse, mutect2, varscan2
- TCERG1L | c.777G>A p.P259= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs751877949, COSV64046023; called by muse, mutect2, varscan2
- TOPORS | c.186G>A p.P62= | Silent (SNP) | VAF 87/229 reads (38%) | catalogued as rs745448839, COSV62116260; called by muse, mutect2, varscan2
- UGT2B4 | c.810C>G p.L270= | Silent (SNP) | VAF 55/101 reads (54%) | catalogued as COSV59315491, COSV59321298; called by muse, mutect2, varscan2
- ZNF831 | c.2370A>G p.R790= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV64037802; called by muse, mutect2, varscan2
- CDKL1 | c.742-1519C>T | Intron (SNP) | VAF 14/37 reads (38%) | catalogued as rs778665241, COSV99367489, COSV99367903; called by muse, mutect2, varscan2
- FBXL5 | c.-1G>C | 5'UTR (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100378057; called by muse, mutect2, varscan2
